FM case AD182 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts.
https://portal.gdc.cancer.gov/cases/d9e9d3f5-b68a-4faf-9e92-123f48fafa54

Male, 53.7 years: Cholangiocarcinoma (ICD-O-3 8160/3) of the liver; primary biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
